Somatic mutation profile of tumor specimen MP2PRT-PAPKCL-TMP1-A (aliquot MP2PRT-PAPKCL-TMP1-A-1-0-D-A83A-36) from MP2PRT case MP2PRT-PAPKCL, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.5 years (1,643 days).
Specimen MP2PRT-PAPKCL-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 65076c0f-2d22-4774-9d6c-d133f86a11a4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAPKCL-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAPKCL-NB1-A-1-0-D-A83A-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7099a7b1-67ab-483d-88c1-b17ab6dc4f72

The open-access MAF lists 16 somatic variants for this specimen: 15 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 11, In Frame Del 2, Silent 1, Nonsense Mutation 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 25/321 reads (8%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- AP1G2 | c.1631G>A p.R544H | Missense Mutation (SNP) | VAF 66/277 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.233); catalogued as rs375677387; called by muse, mutect2, varscan2
- GGT5 | c.458G>A p.R153H | Missense Mutation (SNP) | VAF 144/564 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.298); catalogued as rs373209437; called by muse, varscan2
- HIF1AN | c.412C>T p.R138* | Nonsense Mutation (SNP) | VAF 8/230 reads (3%) | catalogued as rs1397875552; called by muse, mutect2
- PTPN13 | c.4250G>A p.R1417H (on ENST00000411767 / NM_080683.3; = p.R1398H on NM_006264.3) | Missense Mutation (SNP) | VAF 54/192 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs528674242, COSV57408559; called by muse, mutect2, varscan2
- ZNF469 | c.10625C>T p.A3542V (on ENST00000437464; = p.A3570V on NM_001367624.2) | Missense Mutation (SNP) | VAF 113/410 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.009); catalogued as rs776001734; called by muse, mutect2, varscan2
- ADCY8 | c.1769C>T p.P590L | Missense Mutation (SNP) | VAF 86/360 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- CCDC120 | c.1613C>G p.P538R | Missense Mutation (SNP) | VAF 88/527 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- EME1 | c.436C>T p.P146S | Missense Mutation (SNP) | VAF 56/371 reads (15%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.895); called by muse, mutect2, varscan2
- IGKV1D-16 | chr2:90100736 CCTCC>T | Missense Mutation (DEL) | VAF 53/179 reads (30%) | called by pindel, varscan2*
- IGLV4-69 | chr22:22031468 ATTCACACAGTGACACAGGCA>TCTTCCAG | Missense Mutation (DEL) | VAF 28/117 reads (24%) | called by pindel, varscan2*
- PSMC6 | c.851_856delinsGCG p.L284_R286delinsRG (on ENST00000612399; = p.L270_R272delinsRG on NM_002806.5 and 1 other RefSeq transcript) | In Frame Del (DEL) | VAF 40/248 reads (16%) | called by pindel, varscan2*
- STIP1 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 63/360 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TAMALIN | c.844G>A p.D282N | Missense Mutation (SNP) | VAF 62/368 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); called by muse, mutect2, varscan2
- TTN | c.49646_49648del p.P16549del (on ENST00000591111; = p.P9125del on NM_003319.4) | In Frame Del (DEL) | VAF 84/361 reads (23%) | called by mutect2, pindel, varscan2
- SECISBP2 | c.1218C>T p.A406= | Silent (SNP) | VAF 34/193 reads (18%) | catalogued as rs759932472; called by muse, mutect2, varscan2
